Surgical pathology report (de-identified scan), TCGA case TCGA-QU-A6IN, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Harvard Beth Israel, specimen TCGA-QU-A6IN-01A (Primary Tumor).

[page 1 of 3]
Pathology Examination

Name Birthdate Age Sex Pathology #

Report to:

Gross Description by:

SPECIMEN SUBMITTED: PROSTATE BX'S.

Procedure date Tissue received Report Date Diagnosed by

Previous biopsies: PROSTATE BX'S.

Diagnosis:

- 1) Lymph nodes, right obturator, dissection (A-C):
No tumor seen in ten lymph nodes (0/10).
- 2) Lymph nodes, left obturator, dissection (D-E):
No tumor seen in five lymph nodes (0/5).
- 3) Prostate gland and seminal vesicles, radical prostatectomy (H-BA):
- A. Prostatic adenocarcinoma, see synopsis report and note.
- B. High grade prostatic intraepithelial neoplasia.
- C. Unremarkable seminal vesicles.
- 4) Soft tissue, left perivesicular, excision (F-G):
Benign fibrovascular and adipose tissue and nerve.

C6CR IADO-3
Adenocarcinoma, acinar
path 8/46/3
Adenocarcinoma, NOS 8/46/3
Site Prostate NOS C61.9

Note: The Gleason score is 7(3+4) with a component of Gleason pattern 5 present in several foci. No definitive extra-prostatic extension is seen. The resections margins are free of tumor.

Prostatic Carcinoma Synopsis

Type of specimen: Prostate and seminal vesicles.

Procedure: Radical prostatectomy.

Tumor type: Adenocarcinoma.

Tumor histologic grade (Gleason's)
See note

Tumor amount (radical prostatectomies)

	Positive slides	Total
Right	5	11

[page 2 of 3]
Right Apex	0	1
Left	4	11
Left apex	0	1

Involves single slide measurement: No.

Vascular/lymphatic invasion: Absent.

Perineural extension: Present, within prostate.

Surgical margins

Inked capsular/soft tissue resection margins: Free.

Inked bladder margin: Free.

Inked apex margin: Free.

Seminal vesicles

Not involved by tumor

Clinical: Adenocarcinoma of the prostate.

Gross: The specimen is received fresh in four containers each labeled with the patient's name,

Part 1 is additionally labeled right obturator lymph node and consists of a 3.6 x 2.5 x 1.2 cm mass of pink to yellow soft tissue. It is entirely submitted in cassettes A-C. Note cassette A contains two bisected lymph nodes.

Part 2 is additionally labeled left obturator lymph node and consists of a 4.7 x 3.6 x 2.5 cm mass of yellow to pink soft tissue that is represented as follows: D = 3 bisected lymph nodes, E = one bisected lymph node and one whole lymph node.

Part 3 is additionally labeled "prostate, long chromic suture on right seminal vesicle" and consists of a 56 gm specimen. The prostate measures 5.2 x 4.4 x 4.0 cm, the left seminal vesicle measures 4.5 x 1.5 x 1.7 cm, and the right seminal vesicle measures 3.5 x 1.4 x 0.9 cm. The left vas deferens measures 2.5 cm in length 0.5 cm in diameter. The right vas deferens measures 3.5 cm in length and 0.5 cm in diameter. The specimen is inked as follows: left = blue, right = black and is serially sectioned apex to base to reveal tan nodular cut surfaces with areas of yellow tissue. The specimen is represented as follows: H-I = apex shaved margin, J = left apex, K = right apex, L = left middle, M = right middle, N-O = left base, P-Z = most basal slice, including base margin (ink is true margin), AA = left seminal vesicle and vas deferens margin, BA = right seminal vesicle and vas deferens margin.

Part 4 is additionally labeled perivesical tissue left and consists of a 1.9 x 0.8 x 0.6 cm mass of tan soft tissue. The margin is inked black. The specimen is sectioned and entirely submitted in cassettes F-G

By his/her signature above, the senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimens(s) and rendered or confirmed the diagnosis(es) related thereto.

[page 3 of 3]
Immunohistochemistry test(s), if applicable, were developed and their performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA - 88) as qualified to perform high complexity clinical laboratory testing.

Diagnosis/Synchronous Primary Noted		

Source: NCI Genomic Data Commons file 810e7314-5f7e-4ff8-a410-632c8d29a5f6 (TCGA-QU-A6IN.11063611-DCFF-427E-89A9-25961C79DF07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).